Somatic mutation profile of tumor specimen TCGA-SR-A6MU-01A (aliquot TCGA-SR-A6MU-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MU, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 49.5 years (18,073 days).
Specimen TCGA-SR-A6MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db8b19e5-cb19-4dee-8ef1-7f8cccb49497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MU-10B (Blood Derived Normal), aliquot TCGA-SR-A6MU-10B-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ec2c942-4fe2-4be2-908d-3f405b08dd2c

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLRT2 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1248212249, COSV58136841; called by muse, mutect2, varscan2
- GRIK1 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775408657, COSV58714756; called by muse, mutect2, varscan2
- HECW2 | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.027); catalogued as COSV53666791; called by muse, mutect2, varscan2
- HYDIN | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs140028548; called by mutect2, varscan2
- NOTCH4 | c.5437T>C p.W1813R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.671); catalogued as rs1207003680; called by muse, mutect2, varscan2
- TCF19 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.551); catalogued as rs779159917; called by muse, mutect2, varscan2
- AHCTF1 | c.1034A>T p.N345I (on ENST00000366508; = p.N319I on NM_015446.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A17 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZEB1 | c.402C>T p.D134= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1360203247; called by muse, mutect2, varscan2
